Somatic mutation profile of tumor specimen TCGA-KM-8476-01A (aliquot TCGA-KM-8476-01A-11D-2310-10) from TCGA case TCGA-KM-8476, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 47.2 years (17,240 days).
Specimen TCGA-KM-8476-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4d81514d-47c7-4466-8646-cbc2b3e67593.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-KM-8476-10A (Blood Derived Normal), aliquot TCGA-KM-8476-10A-01D-2311-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/875ca6f2-adc7-4d94-ace9-7181ac26a043

The open-access MAF lists 26 somatic variants for this specimen: 19 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 17, Silent 7, Nonsense Mutation 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HEATR5A | c.1843C>T p.R615* | Nonsense Mutation (SNP) | VAF 8/93 reads (9%) | catalogued as rs376522134; called by muse, mutect2
- HIC2 | c.1151C>G p.P384R | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs749598595; called by muse, mutect2, varscan2
- HIVEP1 | c.6859G>A p.D2287N | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs747662071; called by muse, mutect2, varscan2
- ICAM1 | c.1435T>C p.Y479H | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1480508060, COSV99320852; called by muse, mutect2
- MFHAS1 | c.2212A>T p.N738Y | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99359612; called by muse, mutect2
- MYH1 | c.5761G>A p.V1921I | Missense Mutation (SNP) | VAF 9/102 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.03); catalogued as COSV99876059; called by muse, mutect2
- OR2M2 | c.74C>T p.T25M | Missense Mutation (SNP) | VAF 150/202 reads (74%) | SIFT tolerated (0.2); PolyPhen benign (0.097); catalogued as rs146796261, COSV100677211; called by muse, mutect2, varscan2
- PCSK5 | c.1262C>T p.A421V | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs1262895317; called by muse, mutect2, varscan2
- PLPP7 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 55/122 reads (45%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.985); catalogued as rs764693403, COSV64836137; called by muse, mutect2, varscan2
- RBM3 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100618745; called by muse, mutect2
- RC3H1 | c.2455G>T p.G819C | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV99281402; called by muse, mutect2
- SDR42E1 | c.1181G>T p.*394Lext*6 | Nonstop Mutation (SNP) | VAF 22/57 reads (39%) | catalogued as COSV61094179; called by muse, varscan2
- TMEM132B | c.1940C>T p.T647M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs750179973, COSV54766965; called by muse, mutect2
- TP63 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 73/178 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); catalogued as COSV53206730; called by mutect2, varscan2
- ADCY8 | c.1493C>T p.S498L | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- DIPK1C | c.317C>A p.A106D | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- GK2 | c.1621G>A p.V541I | Missense Mutation (SNP) | VAF 66/151 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TCHHL1 | c.4C>T p.P2S | Missense Mutation (SNP) | VAF 34/45 reads (76%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.941); called by muse, mutect2, varscan2
- USP10 | c.1335C>A p.F445L | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.71); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ESCO1 | c.2049C>T p.D683= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs369669502; called by muse, mutect2, varscan2
- FNIP2 | c.924G>A p.R308= | Silent (SNP) | VAF 14/322 reads (4%) | catalogued as COSV100032731; called by muse, mutect2
- MGAT3 | c.948C>T p.D316= | Silent (SNP) | VAF 16/27 reads (59%) | catalogued as rs779415182, COSV57865208; called by muse, varscan2
- MYH7B | c.1518C>T p.I506= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as rs770877069; called by muse, mutect2, varscan2
- NRAP | c.2592C>T p.F864= (on ENST00000359988 / NM_001322945.2; = p.F829= on NM_006175.4) | Silent (SNP) | VAF 10/129 reads (8%) | catalogued as rs778892430, COSV100748455; called by muse, mutect2
- SLC7A1 | c.216C>T p.I72= | Silent (SNP) | VAF 26/36 reads (72%) | catalogued as rs149116208; called by muse, varscan2
- ZNF280B | c.1239G>A p.S413= | Silent (SNP) | VAF 98/229 reads (43%) | catalogued as rs141102079; called by muse, mutect2, varscan2
